Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A4V0, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A4V0-01A (Primary Tumor).

[page 1 of 2]
ck

Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

Left thyroid papillary carcinoma confirmed by FNA, left thyroid lobectomy.

Specimens Submitted:

1: Total thyroidectomy

DIAGNOSIS:

1. Total thyroidectomy:

Part # 1

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 2.1 cm.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:

Not identified

ICD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

hw
10/27/12

[page 2 of 2]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received in formalin, labeled "Total thyroidectomy", and consists of a thyroid weighing 13 g. The right lobe measures 3.5 x 2 x 1 cm, the left lobe measures 4 x 2 x 1.2 cm and the isthmus measures 1 x 1 x 0.3 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a nodule. The nodule is located in the left lobe lower pole, measures 2.1 x 1.5 x 1.5 cm, displays white cut surfaces, and is no encapsulated. Sections through the remaining tissue reveal unremarkable cut surfaces. The remaining thyroid parenchyma is red brown and beefy. A representative section of the specimen is submitted for TPS. The remaining tissue is serially sectioned and representatively submitted.

Summary of sections:

N - nodule, entirely submitted

RL - right lobe

LL - left lobe

IS - Isthmus

Summary of Sections:

Part 1: Total thyroidectomy

Block	Sect. Site	PCs
1	IS	0
2	LL	0
4	N	0
2	RL	0

Source: NCI Genomic Data Commons file 45f070f8-9881-4f73-99c3-47a33e362b48 (TCGA-DJ-A4V0.9807707B-9175-467A-A3F5-879E105129FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).